Somatic mutation profile of tumor specimen MMRF_1232_4_BM_CD138pos (aliquot MMRF_1232_4_BM_CD138pos_T1_KHS5U_L09528) from MMRF case MMRF_1232, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.9 years (21,518 days).
Specimen MMRF_1232_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8872044-9899-4960-a62b-0c80682ab843.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1232_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1232_2_PB_Whole_C1_KHS5U_L11074; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3d26365-83c7-447a-b425-b844074c19f6

The open-access MAF lists 131 somatic variants for this specimen: 44 protein-altering or splice-affecting, 26 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 35, Silent 26, Intron 17, RNA 3, 3'Flank 3, Splice Site 2, 5'UTR 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1461875148; called by muse, mutect2, varscan2
- CHRNG | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781249093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.217A>T p.R73W | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67883857; called by muse, mutect2, varscan2
- IGHV1-69 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as rs376711593; called by muse, mutect2, varscan2
- IGHV2-70 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs777686921; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGKV3-20 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1289403379; called by muse, mutect2, varscan2
- IGKV3-20 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs1490129717; called by muse, mutect2, varscan2
- KCNU1 | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1201482161; called by muse, mutect2, varscan2
- NIPA1 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as rs755365260; called by muse, mutect2, varscan2
- POLD2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs1420862721; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1555A>T p.I519F | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs780876162; called by muse, mutect2, varscan2
- UNC5B | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1230109367; called by muse, mutect2, varscan2
- WAPL | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs1357456257; called by muse, mutect2
- ZCCHC14 | c.2198C>T p.P733L (on ENST00000268616; = p.P870L on NM_015144.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs938460080, COSV51889576; called by muse, mutect2, varscan2
- ZCCHC14 | c.1156G>A p.G386R (on ENST00000268616; = p.G523R on NM_015144.3) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769358336; called by muse, mutect2
- ZNF574 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.448); catalogued as rs1207826569; called by muse, mutect2, varscan2
- ZNF726 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1344429192; called by muse, mutect2, varscan2
- AP3M2 | c.129A>C p.E43D | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- ARHGEF28 | c.2862C>A p.F954L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF40 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BPIFB4 | c.1059T>G p.I353M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CMAS | c.450T>A p.H150Q | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ESYT1 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- FXR2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, varscan2
- FXR2 | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, varscan2
- KDM2A | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL34 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- L1CAM | c.408del p.K137Sfs*7 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel
- MUC6 | c.2429C>G p.A810G | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MYO5C | c.3672_3673del p.K1225Afs*4 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- OR6C76 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCOLCE2 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PRDM15 | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RASGRF1 | c.3221A>G p.E1074G | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SPEF2 | c.5436A>C p.R1812S | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D25 | c.1975G>T p.V659F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- THADA | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- TPBG | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL7 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, varscan2
- UBR4 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- USP24 | c.3243C>G p.N1081K | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- YIPF7 | c.499-2A>T p.X167_splice | Splice Site (SNP) | VAF 52/80 reads (65%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C12orf56 | c.1564C>T p.L522= (on ENST00000543942 / NM_001170633.2; = p.L362= on NM_001099676.3) | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs748664915; called by muse, mutect2, varscan2
- CDHR1 | c.1881G>A p.G627= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- CHRM2 | c.756C>T p.D252= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs531986911, COSV57765140, COSV57779856; called by muse, mutect2, varscan2
- CRACDL | c.1875G>A p.A625= | Silent (SNP) | VAF 25/35 reads (71%) | called by muse, mutect2, varscan2
- DLL3 | c.1401A>G p.P467= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- DST | c.15657G>A p.K5219= (on ENST00000361203 / NM_001374722.1; = p.K2807= on NM_015548.5) | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as COSV55013011; called by muse, mutect2, varscan2
- FZD1 | c.1116C>T p.G372= | Silent (SNP) | VAF 70/143 reads (49%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1818G>A p.K606= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs367953381; called by muse, varscan2
- IGHV2-70 | c.156A>G p.G52= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs1232476476; called by muse, varscan2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs187704106; called by muse, mutect2, varscan2
- IGKV3-20 | c.318G>A p.V106= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs561691766; called by muse, varscan2
- KRTAP10-6 | c.54C>T p.R18= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as rs373580644; called by muse, mutect2, varscan2
- LARGE2 | c.76C>T p.L26= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- LRFN4 | c.1104G>A p.V368= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- MUC5B | c.3201C>G p.P1067= | Silent (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- NPRL2 | c.1104G>T p.R368= | Silent (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- PCNT | c.27C>T p.R9= | Silent (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- PEAR1 | c.2703C>T p.F901= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV52774886; called by muse, mutect2, varscan2
- PPP1R12C | c.315G>A p.L105= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1279683088; called by muse, mutect2, varscan2
- PRKCH | c.1512G>T p.G504= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- RBM14 | c.1884G>A p.P628= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs767025849; called by muse, mutect2, varscan2
- RTTN | c.6405C>T p.P2135= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs1405270635; called by muse, mutect2, varscan2
- SOWAHA | c.621A>G p.A207= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101097747; called by muse, mutect2, varscan2
- TG | c.3705G>T p.S1235= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- TTC7A | c.1050C>T p.L350= | Silent (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- AC078899.1 | n.1169G>C | RNA (SNP) | VAF 115/213 reads (54%) | called by muse, mutect2, varscan2
- AIFM2 | c.*617_*621del | 3'UTR (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- AL035461.3 | c.*1989T>C | 3'UTR (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- AL590143.1 | chr6:84688716 A>C | 3'Flank (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- AMFR | c.*32G>A | 3'UTR (SNP) | VAF 43/135 reads (32%) | catalogued as rs774236186, COSV51920565; called by muse, mutect2, varscan2
- ANKLE2 | c.1892-782G>A | Intron (SNP) | VAF 57/94 reads (61%) | called by muse, mutect2, varscan2
- BCL2L11 | c.*2342T>C | 3'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as rs1030674999; called by muse, mutect2
- BCLAF1 | c.*288A>C | 3'UTR (SNP) | VAF 83/165 reads (50%) | called by muse, mutect2, varscan2
- BMP6 | c.*1061_*1063del | 3'UTR (DEL) | VAF 29/67 reads (43%) | called by pindel, varscan2
- CARMIL1 | c.614+1454G>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- CCDC115 | chr2:130342640 A>T | 5'Flank (SNP) | VAF 19/39 reads (49%) | catalogued as rs1291692631; called by muse, mutect2, varscan2
- CCDC125 | c.*2441C>G | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- CEP97 | c.*1206C>A | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- CHTOP | c.404-77A>G | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100904749; called by muse, mutect2
- CLEC4E | c.*1238C>T | 3'UTR (SNP) | VAF 37/87 reads (43%) | catalogued as rs970302815; called by muse, mutect2, varscan2
- CREBRF | c.*544_*547del | 3'UTR (DEL) | VAF 8/72 reads (11%) | catalogued as rs1208503634; called by pindel, varscan2
- CUX1 | c.*3470_*3471del | 3'UTR (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- DMRTA2 | c.*654T>G | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- EIF4A1 | c.996+107C>T | Intron (SNP) | VAF 14/68 reads (21%) | called by muse, varscan2
- FUT8 | c.*1184T>A | 3'UTR (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- FZD3 | c.*6513del | 3'UTR (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- GAREM1 | c.*1302dup | 3'UTR (INS) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- GATM | c.*144T>C | 3'UTR (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- GRAMD2B | c.128+10855C>T | Intron (SNP) | VAF 83/105 reads (79%) | called by muse, mutect2, varscan2
- HYOU1 | c.*1269C>T | 3'UTR (SNP) | VAF 26/39 reads (67%) | called by muse, mutect2, varscan2
- IGBP1 | c.-455C>T | 5'UTR (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.*628C>T | 3'UTR (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- KDM2A | c.*441_*455del | 3'UTR (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- LINC01101 | n.232C>T | RNA (SNP) | VAF 91/196 reads (46%) | called by muse, mutect2, varscan2
- LINC01559 | n.400+56T>C | Intron (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- LPP | c.*4322A>G | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by mutect2, varscan2
- LTB | c.208+86A>G | Intron (SNP) | VAF 63/113 reads (56%) | catalogued as rs551098549; called by muse, mutect2, varscan2
- LTB | c.162+82C>T | Intron (SNP) | VAF 45/77 reads (58%) | catalogued as rs569397869; called by muse, mutect2, varscan2
- MC5R | chr18:13826915 A>T | 3'Flank (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- MFSD2B | c.1170-33G>T | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- MIR5195 | n.52G>A | RNA (SNP) | VAF 35/75 reads (47%) | catalogued as rs1307217838; called by muse, mutect2, varscan2
- MTG1 | c.112+150C>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- NAP1L5 | c.*1088A>C | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- NSD3 | c.1809+246dup | Intron (INS) | VAF 42/84 reads (50%) | called by mutect2, pindel, varscan2
- OBSCN | c.18662-1532A>G | Intron (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+332T>G | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- PDE4D | c.*3994C>T | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- PLIN4 | c.*140G>A | 3'UTR (SNP) | VAF 27/54 reads (50%) | catalogued as rs1274713549; called by muse, mutect2, varscan2
- POLR3H | c.*820G>A | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-4004G>A | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- RAB22A | c.*5045C>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs6070436, COSV54831888; called by muse, varscan2
- RGS14 | c.627+51G>A | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.1540-91C>G | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SAT2 | c.346-32C>A | Intron (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- SFMBT2 | c.*2931C>T | 3'UTR (SNP) | VAF 45/63 reads (71%) | called by muse, mutect2, varscan2
- SHPK | c.*85G>T | 3'UTR (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- SLC25A6 | c.*246T>C | 3'UTR (SNP) | VAF 71/157 reads (45%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.*757C>T | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624607 T>G | 3'Flank (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- SOCS4 | c.*5004C>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, varscan2
- TNFRSF11A | c.*1705G>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- VAMP2 | c.*315T>C | 3'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, varscan2
- ZDHHC11 | c.-104G>C | 5'UTR (SNP) | VAF 29/70 reads (41%) | catalogued as rs1279690335; called by muse, mutect2, varscan2
- ZNF44 | c.*614C>T | 3'UTR (SNP) | VAF 64/114 reads (56%) | catalogued as rs779800868; called by muse, mutect2, varscan2
- ZNF525 | c.*1498A>C | 3'UTR (SNP) | VAF 64/367 reads (17%) | catalogued as COSV100802388; called by muse, mutect2, varscan2
- ZNF99 | c.*1132C>A | 3'UTR (SNP) | VAF 33/39 reads (85%) | called by muse, mutect2, varscan2
